Somatic mutation profile of tumor specimen BA3030D (aliquot aq-BA3030D) from BEATAML1.0 case 2046, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Atypical chronic myeloid leukemia, BCR/ABL negative; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,924 days).
Specimen BA3030D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d1a37ef-52d4-4d83-a55b-6f7fee23f3d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2188D (Solid Tissue Normal), aliquot aq-BA2188D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1756175-b84d-4c5b-b821-93f7acc51b8d

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C5orf38 | c.167C>A p.A56E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57413308; called by muse, mutect2
- UNKL | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); catalogued as rs769005974; called by muse, varscan2
- RHOD | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ATG2B | c.2889T>C p.N963= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- KRT4 | c.315C>T p.P105= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs555229510; called by muse, mutect2, varscan2
- PLXNA2 | c.-63C>T | 5'UTR (SNP) | VAF 33/75 reads (44%) | catalogued as COSV65440323; called by muse, mutect2, varscan2
